Surgical pathology report (de-identified scan), TCGA case TCGA-EY-A210, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of North Carolina, specimen TCGA-EY-A210-01A (Primary Tumor).

[page 1 of 6]
ICD-03

mixed endometrioid + serous (code to highest)

adenocarcinoma, perovs, NOS 8441/3

Site: endometrium C54.1 lw 4/8/11

SURGICAL PATHOLOGY REVISED REPORT

Case Number :

Diagnosis:

A: Lymph nodes, left periaortic, removal

- Metastatic adenocarcinoma in one lymph node (1/1)
- Adenocarcinoma present within lymphovascular spaces

B: Uterus and cervix, bilateral tubes and ovaries, hysterectomy and bilateral salpingo-oophorectomy:

Location of tumor: Endometrium

Histologic type: Mixed serous adenocarcinoma, 80% and high grade endometrioid

adenocarcinoma, 20%, FIGO grade 3C2 (architectural grade 3, nuclear grade 3)

Histologic grade (FIGO): 3

Extent of invasion: Myometrium

Myometrial invasion: Inner half

Depth: 0.6 cm Wall thickness: 1.6 cm Percent: 38%

Serosal involvement: Not identified

Lower uterine segment involvement: Present

Cervical involvement: Direct extension not identified; tumor present within lymphovascular spaces

Adnexal involvement (see below): Luminal, non invasive adenocarcinoma within the fallopian tubes

Other sites: None

Cervical/vaginal margin and distance: Negative, widely free of

[page 2 of 6]
tumor

Lymphovascular space invasion: Prominent

Regional lymph nodes (see other specimens A, C, D and E):

Total number involved: 13

Total number examined: 28

Other pathologic findings: None

Tumor estrogen receptor and progesterone receptor
immunohistochemistry results:

Estrogen receptor: Positive, 1+, 40%

Progesterone receptor: Negative

AJCC Pathologic Stage: pT1a pN2

FIGO (2008 classification) Stage grouping: IIIC2

These stages are based on information available at the time of
this report, and

are subject to change pending additional information and
clinical review.

Ovary, right, oophorectomy:

- No specific pathologic abnormality

Ovary, left, oophorectomy:

- No specific pathologic abnormality

Fallopian tube, right, salpingectomy:

- Adenocarcinoma present within lumen of fallopian tube
- No invasive adenocarcinoma identified

Fallopian tube, left, salpingectomy:

- Adenocarcinoma present within lumen of fallopian tube
- No invasive adenocarcinoma identified

C: Lymph nodes, right periaortic, removal

- Metastatic adenocarcinoma present in six of seven lymph nodes
(6/7)

- Adenocarcinoma present within lymphovascular spaces

D: Lymph nodes, right pelvic, removal

- Metastatic adenocarcinoma present in one of seven lymph nodes
(1/7)

- Adenocarcinoma present within lymphovascular spaces

[page 3 of 6]
E: Lymph nodes, left pelvic, removal

- Metastatic adenocarcinoma present in five of thirteen lymph nodes (5/13)

- Adenocarcinoma present within lymphovascular spaces

Clinical History:

- year-old with endometrial cancer.

Gross Description:

Received are five appropriately labeled containers.

Container A is additionally labeled "left periaortic." It consists of a 3.1 x 1.6 x 0.8 cm fatty pink/yellow lymph node which is serially sectioned and submitted in blocks A1 and A2, .

Container B is additionally labeled "uterus, cervix, tubes and ovaries."

Adnexa: bilateral attached

Weight: 199 grams

Shape: normal

Dimensions:

height: 9.6 cm

anterior to posterior width: 3.8 cm

breadth at fundus: 4.9 cm

Serosa: pink/tan, smooth and glistening

Cervix: 3.7 cm long x 2.2 cm in diameter

length of endocervical canal: 2.5 cm

ectocervix: erythematous and smooth

endocervix: trabeculated

Endomyometrium:

length of endometrial cavity: 6.4 cm

width of endometrial cavity at fundus: 3.9 cm

tumor findings:

dimensions: 6.3 x 5.9 x 4.3 cm (protruding into the cavity)

appearance: homogeneous, tan, fungating and friable; Loosely attached

to the mass is a 7.1 x 2.5 x 0.3 cm aggregate of loosely adherent red/brown blood clot.

location and extent: The mass occupies the entire endometrial cavity and extends to the anterior and posterior lower uterine segment endocervical canal interface.

[page 4 of 6]
myometrial invasion: outer one half
thickness of myometrial wall at deepest gross invasion: 1.7 cm
other findings or comments: The anterior and posterior cervical
stroma on
cut section has an ill-defined firm, smooth, yellow/tan
area (2.8 x 1.7 x 1.6 cm) that is 0.1 cm to the posterior soft
tissue
margin (inked black) and 0.3 cm to the anterior
cervical soft tissue margin (inked blue).

Adnexa:

Right ovary:

dimensions: 2.6 x 1.2 x 0.7 cm
external surface: unremarkable
cut surface: unremarkable

Right fallopian tube:

dimensions: 5.3 cm long x 0.5 cm in diameter
other findings: none

Left ovary:

dimensions: 3.1 x 0.8 x 0.8 cm
external surface: unremarkable
cut surface: unremarkable

Left fallopian tube:

dimensions: 6.4 cm long x 0.5 cm in diameter
other findings: none

Lymph nodes: n/a

Other comments: none

Digital photograph taken: not taken

Tissue submitted for special investigations: yes; Tumor given to
Tissue
Procurement

Block Summary:

B1 - anterior cervix
B2 - perpendicular of anterior lower uterine segment
B3 - anterior corpus, full thickness
B4 - posterior cervix
B5 - perpendicular of posterior lower uterine segment
B6 - posterior corpus
B7 - full thickness section at the fundus
B8 - right ovary
B9 - right fallopian tube
B10 - left ovary
B11 - left fallopian tube

[page 5 of 6]
B12-B15 - additional sections of tumor

Container C is additionally labeled "right periaortic." It consists of a 4.2 x 2.6 x 0.8 cm portion of fibrofatty tissue that is dissected for lymph node candidates. Eight lymph nodes are identified ranging from 0.6 x 0.5 x 0.3 cm up to 3.1 x 1.3 x 0.6 cm in greatest dimension.

Block Summary:

C1 - two lymph nodes, one inked green and bisected
C2 - one lymph node, bisected
C3 - one lymph node, serially sectioned
C4 - one lymph node, serially sectioned
C5 - one lymph node, serially sectioned
C6 - one lymph node, serially sectioned
C7,C8 - one lymph node, serially sectioned

Container D is additionally labeled "right pelvic." It consists of a 4.7 x 3.6 x 1.6 cm aggregate of fibrofatty tissue that is dissected for lymph node candidates. Nine lymph nodes are identified ranging from 0.3 cm in greatest dimension up to 2.6 x 1.6 x 0.7 cm in greatest dimension.

Block Summary:

D1 - three lymph nodes
D2 - one lymph node
D3 - two lymph nodes, each bisected, one inked green
D4 - one lymph node, bisected
D5 - one lymph node, serially sectioned
D6,D7 - one lymph node, serially sectioned

Container E is additionally labeled "left pelvic." It consists of a 4.9 x 2.3 x 1.9 cm aggregate of fibrofatty tissue and a scant amount of blood clot that is dissected for lymph node candidates. Twelve lymph nodes are identified ranging from 0.6 x 0.4 x 0.3 cm up to 2.1 x 1.0 x 0.7 cm in greatest

[page 6 of 6]
dimension.

Block Summary:

- E1 - five lymph nodes
- E2 - two lymph nodes, each bisected, one inked green
- E3 - two lymph nodes, each bisected, one inked green
- E4 - one lymph node, serially sectioned
- E5 - one lymph node, serially sectioned
- E6 - one lymph node, serially sectioned

Light Microscopy:

Light microscopic examination is performed by Dr.

Signature

Attending Pathologist:

I have personally conducted the evaluation of the above specimens and have rendered the above diagnosis(es).

Electronically Signed by:

Date

Source: NCI Genomic Data Commons file 70fcb384-6deb-44ae-bcda-1e35ad8837a5 (TCGA-EY-A210.51A98C43-6A6A-4027-8E92-B3B9AA1A63D4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).